Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A6V7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A6V7-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

FINAL

Report Type Pathology Report
Date of Event
Sex
Authored by
Hosp/Group
Record Status FINAL

ICD-O-3
Carcinoma, squamous
cell, non-keratinizing
8872/3
Site B Jonsil NOS
C09.9
JW 8/2/13

FINAL DIAGNOSIS:

TONSIL, RIGHT, BIOPSY

FRAGMENT OF SQUAMOUS CELL CARCINOMA, NON-KERATINIZING.

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received unfixed for intraoperative consultation, labeled with the patient's name, initials XXX, and "biopsy right tonsil". It consists of a 0.7 x 0.6 x 0.3 cm aggregate of tan-red irregular soft tissue fragments.

The

specimen is entirely resubmitted for permanent, in cassette AFS.

Formalin Exposure Time: 83 hours

Grossed by:

INTRAOPERATIVE CONSULTATION:

1AFS: TONSIL, RIGHT, BIOPSY (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. MALIGNANT

C. SQUAMOUS CELL CARCINOMA

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the

the CLIA

as required by

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement

[page 2 of 2]
Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

PATIENT HISTORY:

CHIEF COMPLAINT: Unknown primary, previous neck dissection for right neck mass.

Per TSS - FNA inconclusive. Later determined to be met to primary SCC of tonsil.

PRE-OP DIAGNOSIS: Not provided.

POST-OP DIAGNOSIS: Not provided.

BCL

PROCEDURE: Robotic, base of tongue.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Biopsy Right Tonsil

Taken: Received:

Stain/Block

HHE x 1 AFS

H&E x 1 AFS

TC1

Source: NCI Genomic Data Commons file 717a33cd-b633-4cc0-bf3a-1f987efcdd44 (TCGA-CN-A6V7.49DD2EB3-77AB-4535-98BD-13536516E9BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).